Gene-level copy-number profile of tumor specimen TCGA-LI-A67I-01A from TCGA case TCGA-LI-A67I, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 75.8 years (27,671 days).
Specimen TCGA-LI-A67I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.7198d4ba-e461-4023-a007-e36c95fe4d2b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LI-A67I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7aae4eb9-c9f4-4fdf-ab83-2ebfa0cf7b1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 4,348; copy number 2: 32,310; copy number 3: 16,234; copy number 4: 5,058; copy number 5: 1,759; copy number 6: 36; copy number 8: 44; copy number 11: 2; copy number 16: 4; copy number 17: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LI-A67I-01A-31D-A306-01): tumor purity 0.77, ploidy 2.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:65,233,056–66,552,544, 16 genes (within-gene range 0–2): AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1, RNA5SP428, AC012325.1, CDH5, LINC00920, BEAN1, AC132186.1, BEAN1-AS1, AC010542.3, TK2, AC010542.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,846 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,534,449–90,047,109, 1,051 genes, copy number 5 (broad region; genes not listed).
- chr2:70,447,284–70,554,193, 2 genes, copy number 11 (within-gene range 2–11): TGFA, TGFA-IT1.
- chr2:70,629,657–70,648,761, 1 gene, copy number 17: AC005234.2.
- chr5:58,198–1,380,107, 52 genes, copy number 6–8 (within-gene range 3–8): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32.
- chr6:53,336,943–54,945,099, 31 genes, copy number 5 (within-gene range 4–5): RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B.
- chr10:44,712–38,783,108, 675 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:72,742,314–72,868,146, 1 gene, copy number 16 (within-gene range 1–16): NETO1.
- chr18:72,853,321–73,745,232, 6 genes, copy number 5–16: MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P.
- chr22:20,129,456–20,592,218, 27 genes, copy number 8: ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1.

Autosomal genes at a single copy (total copy number 1): 3,319. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
